Somatic mutation profile of tumor specimen TCGA-AX-A2H8-01A (aliquot TCGA-AX-A2H8-01A-11D-A17D-09) from TCGA case TCGA-AX-A2H8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 64.2 years (23,448 days).
Specimen TCGA-AX-A2H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9120ac03-3cbc-41f8-8220-99e63a87ae70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2H8-11A (Solid Tissue Normal), aliquot TCGA-AX-A2H8-11A-11D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5feda389-15ed-49f3-a2ca-6746ef9f52de

The open-access MAF lists 53 somatic variants for this specimen: 46 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 6, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 36/44 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 35/61 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ABCB8 | c.1678C>G p.L560V (on ENST00000297504 / NM_001282291.2; = p.L543V on NM_007188.5) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1462178251, COSV99874999; called by muse, mutect2, varscan2
- ADGRV1 | c.16678G>T p.V5560L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV101316493; called by muse, mutect2, varscan2
- ANKRD40 | c.196_197insA p.S66Yfs*4 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | catalogued as COSV99560635; called by mutect2, pindel, varscan2
- CACNA1B | c.4351C>T p.R1451W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201000023, COSV53125838; called by muse, mutect2, varscan2
- CATSPER4 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs756874985, COSV100128515; called by muse, mutect2, varscan2
- CCDC125 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs766137485, COSV67287657; called by muse, mutect2, varscan2
- CDC73 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100813989; called by muse, mutect2, varscan2
- CELF2 | c.541A>G p.T181A (on ENST00000416382 / NM_001025077.3; = p.T188A on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV100258371; called by muse, mutect2, varscan2
- CENPS-CORT | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as rs1263053952, COSV100259266, COSV57630961; called by muse, mutect2, varscan2
- DCSTAMP | c.878T>G p.L293R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99886950; called by muse, mutect2, varscan2
- DDX54 | c.375G>A p.K125= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100014198; called by muse, mutect2, varscan2
- EPPK1 | c.3864C>G p.F1288L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.058); catalogued as COSV101599952, COSV73262238; called by muse, mutect2, varscan2
- EPPK1 | c.3863T>A p.F1288Y | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101599953; called by muse, mutect2, varscan2
- GIGYF2 | c.3812G>A p.R1271Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as COSV101004599; called by muse, mutect2, varscan2
- HEATR5A | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV101120531; called by muse, mutect2, varscan2
- HIVEP3 | c.6170G>A p.G2057D | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99913973; called by muse, mutect2, varscan2
- KIF21A | c.3967A>T p.I1323F (on ENST00000361418 / NM_001378440.1; = p.I1310F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100735647, COSV100735770; called by muse, mutect2, varscan2
- KIR2DL1 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 60/376 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV99382951, COSV99383651; called by muse, varscan2
- LIPC | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV100134860; called by muse, mutect2, varscan2
- MTA1 | c.1843A>C p.M615L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100231767; called by muse, mutect2, varscan2
- NCAM2 | c.1384A>T p.I462F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV99525198; called by muse, mutect2, varscan2
- NID2 | c.3254T>G p.I1085R | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV99357245; called by muse, mutect2, varscan2
- NPY2R | c.1082A>T p.K361M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100279430, COSV100279910, COSV61527383, COSV61528948; called by muse, mutect2, varscan2
- ODAM | c.635A>C p.E212A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV101258105; called by muse, mutect2, varscan2
- PCDHA2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65367063, COSV65371452; called by muse, mutect2, varscan2
- PI4KB | c.1265G>A p.R422Q (on ENST00000368873 / NM_001369623.1; = p.R434Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1267222624, COSV55022226; called by muse, mutect2, varscan2
- PIK3CA | c.2174A>G p.D725G | Missense Mutation (SNP) | VAF 86/120 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV55889334; called by muse, mutect2, varscan2
- PPP2R1A | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV59042219, COSV59042372, COSV59048123; called by muse, mutect2, varscan2
- PTCH2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs144561012; called by muse, mutect2, varscan2
- PXDN | c.3750G>T p.W1250C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99414882; called by muse, mutect2, varscan2
- RNF43 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs760556127, COSV101348353, COSV68458295; called by muse, mutect2, varscan2
- SEC24C | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs142319255; called by muse, mutect2, varscan2
- SERHL2 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs771070052, COSV59670010; called by muse, mutect2, varscan2
- SERPINB10 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99449720; called by muse, mutect2
- SF3B1 | c.439A>G p.M147V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100135746; called by muse, mutect2
- SLC5A8 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV101610606, COSV73311364; called by muse, mutect2, varscan2
- SMCR8 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs143903375; called by muse, mutect2, varscan2
- SPAG17 | c.4831G>T p.D1611Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV100310545; called by muse, mutect2, varscan2
- USPL1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.421); catalogued as rs1285848939, COSV99687587; called by muse, mutect2, varscan2
- ZFHX3 | c.3076G>T p.E1026* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | catalogued as COSV51735100; called by muse, mutect2, varscan2
- C6 | c.592_596dup p.L200Ifs*53 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | called by mutect2, varscan2
- IGHV6-1 | c.305T>A p.F102Y | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- ZBTB7B | c.1139del p.G380Vfs*10 (on ENST00000292176; = p.G414Vfs*10 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- FAM222B | c.1002C>T p.T334= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs554449532, COSV100368725; called by muse, mutect2, varscan2
- HEG1 | c.1026G>A p.T342= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs377183884; called by muse, mutect2, varscan2
- HLX | c.948G>A p.T316= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100854621; called by muse, mutect2, varscan2
- RYR2 | c.3822C>T p.D1274= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs761365777, COSV100771893; called by mutect2, varscan2
- SCNN1G | c.1830C>T p.H610= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1408911812, COSV100264499; called by muse, mutect2, varscan2
- ZNF680 | c.315A>G p.Q105= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100549334, COSV59015211; called by mutect2, varscan2
- NRDC | c.-2G>T | 5'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100703857; called by muse, mutect2, varscan2
